Somatic mutation profile of tumor specimen 0DII43 from CCDI case PBBVJL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.1 years (1,845 days).
Specimen 0DII43: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b867c810-bab0-485b-bbf8-12dfe76b14ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII33 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d629c3cf-9f59-4d18-a885-6e9e6f4bfb6d

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 4, Intron 3, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 132/529 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- TFG | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 189/1173 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs587777175, CM1314548, COSV53749892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF26 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 212/812 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV62851485; called by muse, mutect2, varscan2
- CPE | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 182/798 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs138641684; called by muse, mutect2, varscan2
- EIF2B1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 90/943 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs745385760, COSV71193772; called by muse, mutect2
- HSD17B13 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 138/735 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1035712584; called by muse, mutect2, varscan2
- MLLT3 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 98/586 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV63498019; called by muse, varscan2
- MMP10 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 139/1101 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54246407; called by muse, mutect2, varscan2
- MYNN | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 432/1360 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV62992279; called by muse, mutect2, varscan2
- PDP2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs778015440, COSV61241441; called by muse, mutect2
- SCAF4 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 64/1226 reads (5%) | catalogued as rs867668039, COSV99741855; called by muse, mutect2
- WASF1 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 159/958 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63935415; called by muse, mutect2, varscan2
- WDR17 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 72/812 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs201283359; called by muse, mutect2
- ZBBX | c.434T>A p.V145E | Missense Mutation (SNP) | VAF 229/769 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56800904; called by muse, mutect2, varscan2
- AARS1 | c.1828A>C p.I610L | Missense Mutation (SNP) | VAF 167/741 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL14A1 | c.2158C>G p.P720A | Missense Mutation (SNP) | VAF 184/1972 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- CROCC2 | c.4910G>A p.W1637* | Nonsense Mutation (SNP) | VAF 103/572 reads (18%) | called by muse, mutect2, varscan2
- DEFB136 | c.227G>C p.W76S | Missense Mutation (SNP) | VAF 168/1977 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- DNAH9 | c.9108C>G p.Y3036* | Nonsense Mutation (SNP) | VAF 143/783 reads (18%) | called by muse, mutect2, varscan2
- EPN2 | c.1361T>C p.I454T | Missense Mutation (SNP) | VAF 163/801 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- H1-3 | c.534_535del p.K179Nfs*13 | Frame Shift Del (DEL) | VAF 90/476 reads (19%) | called by mutect2, varscan2
- INPP4B | c.1158T>A p.H386Q | Missense Mutation (SNP) | VAF 294/1315 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- INTU | c.1721T>G p.L574W | Missense Mutation (SNP) | VAF 201/1155 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- NEK5 | c.649T>C p.C217R | Missense Mutation (SNP) | VAF 47/734 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OTOG | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 219/1146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCOR2 | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 52/1032 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- SLC13A3 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 431/1253 reads (34%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SLU7 | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 137/700 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TUB | c.1276C>A p.Q426K (on ENST00000299506 / NM_177972.3; = p.Q481K on NM_003320.4) | Missense Mutation (SNP) | VAF 147/820 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WDR90 | c.3457C>G p.H1153D | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- YTHDC1 | c.750T>G p.Y250* | Nonsense Mutation (SNP) | VAF 19/310 reads (6%) | called by muse, mutect2
- ASAH1 | c.1215T>G p.P405= | Silent (SNP) | VAF 100/3354 reads (3%) | called by muse, mutect2
- LCE1D | c.312G>C p.G104= | Silent (SNP) | VAF 141/603 reads (23%) | called by muse, mutect2, varscan2
- SLC39A3 | c.9A>G p.K3= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as rs1285799427; called by muse, mutect2
- SYMPK | c.2505C>A p.G835= | Silent (SNP) | VAF 198/1041 reads (19%) | called by muse, mutect2, varscan2
- TCF25 | c.2001C>T p.D667= | Silent (SNP) | VAF 118/602 reads (20%) | catalogued as rs764853648; called by muse, varscan2
- UPP2 | c.246C>G p.L82= | Silent (SNP) | VAF 210/1105 reads (19%) | called by muse, mutect2, varscan2
- KLF17 | c.-73A>C | 5'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2
- MROH1 | c.948+35C>T | Intron (SNP) | VAF 59/471 reads (13%) | called by muse, mutect2, varscan2
- PREX2 | c.-16C>T | 5'UTR (SNP) | VAF 83/877 reads (9%) | called by muse, mutect2
- SACM1L | c.333+35C>T | Intron (SNP) | VAF 166/491 reads (34%) | catalogued as rs201533862; called by muse, mutect2, varscan2
- SUN1 | c.1022-65C>T | Intron (SNP) | VAF 168/951 reads (18%) | catalogued as rs1030099284; called by muse, mutect2, varscan2
